Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A3EZ, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A3EZ-01A (Primary Tumor).

FINAL DIAGNOSIS:**PART 1: THYROID, TOTAL THYROIDECTOMY (19 GRAMS) -**

- A. PAPILLARY THYROID CARCINOMA, THREE FOCI, RIGHT LOBE AND ISTHMUS (SIZE RANGE: 0.1 - 2.4 CM).
- B. LARGEST FOCUS: RIGHT LOBE - CONVENTIONAL TYPE WITH EXTENSIVE EXTRATHYROIDAL EXTENSION INTO SKELETAL MUSCLE
- i. ANGIOLYMPHATIC AND PERINEURAL INVASION PRESENT.
- ii. FOCALLY PRESENT AT MARGIN.
- C. BACKGROUND CHRONIC LYMPHOCYTIC THYROIDITIS.
- D. ONE LYMPH NODE, ISTHMIC, NO TUMOR PRESENT (0/1).
- E. PATHOLOGIC STAGE: pT3 N1b.

PART 2: LYMPH NODES CENTRAL COMPARTMENT, SELECTIVE NECK DISSECTION -

- A. METASTATIC PAPILLARY THYROID CARCINOMA IN FIVE OF NINE LYMPH NODES (5/9), NO EXTRANODAL EXTENSION.
- B. NORMOCELLULAR PARATHYROID TISSUE.
- C. SCANT FRAGMENT OF THYMIC TISSUE.
- D. TISSUE ENTIRELY SUBMITTED FOR HISTOLOGIC EVALUATION.

PART 3: LYMPH NODES RIGHT LATERAL NECK, SELECTIVE DISSECTION -

- A. METASTATIC PAPILLARY THYROID CARCINOMA IN ONE OF THIRTY TWO LYMPH NODES (1/32), NO EXTRANODAL EXTENSION.
- B. TISSUE ENTIRELY SUBMITTED FOR HISTOLOGIC EVALUATION.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY THYROID TUMORS**

SPECIMEN TYPE: Total Thyroidectomy
TUMOR SITE: Right Lobe, Isthmus
TUMOR FOCALITY: Multifocal
TUMOR SIZE (largest nodule): Greatest Dimension: 2.4 cm
HISTOLOGIC TYPE:** Papillary carcinoma
TNM DESCRIPTORS: m
PRIMARY TUMOR (pT): pT3
REGIONAL LYMPH NODES (pN): pN1b
Number of regional lymph nodes examined: 42
Number of regional lymph nodes involved: 6
EXTRANODAL EXTENSION: Not identified
DISTANT METASTASIS (pM): Not applicable
EXTRATHYROIDAL EXTENSION: Present
Extent: Extensive
MARGINS: Margin(s) involved by carcinoma
Site(s) of involvement: right
LYMPH-VASCULAR INVASION: Present
ADDITIONAL PATHOLOGIC FINDINGS: Thyroiditis

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Thyroid cancer
PROCEDURE: Total thyroidectomy/neck dissection
SPECIFIC CLINICAL QUESTION: Not answered
OUTSIDE TISSUE DIAGNOSIS: Not answered

1CD-0-3

carcinoma, papillary, thyroid P260/3

Site: thyroid NOS C73.9
11/4/11

Source: NCI Genomic Data Commons file da8e4e45-e2b5-4f22-b06d-902a542ef19d (TCGA-BJ-A3EZ.32D8F45C-7FFE-4F34-8D8E-1A2B35B09EF7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).